Somatic mutation profile of tumor specimen HTMCP-03-06-02206-01A (aliquot HTMCP-03-06-02206-01A-01D-6194) from CGCI case HTMCP-03-06-02206, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02206-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4438916-1363-48ab-b1d3-21f6a619b852.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02206-10A (Blood Derived Normal), aliquot HTMCP-03-06-02206-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6552d7c9-a4f1-4570-9083-c3dc032c6b99

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 2, Intron 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 41/223 reads (18%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- ADCY1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52033824; called by muse, mutect2
- CHD8 | c.4592G>A p.R1531H (on ENST00000646647 / NM_001170629.2; = p.R1252H on NM_020920.4) | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs192277407, COSV63219166; called by muse, mutect2, varscan2
- FNDC1 | c.5172G>A p.T1724= | Splice Region (SNP) | VAF 59/226 reads (26%) | catalogued as rs773943155, COSV51937393, COSV99794955; called by muse, mutect2, varscan2
- NLRP5 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs577761633, COSV66761737; called by muse, mutect2, varscan2
- OR2T34 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as COSV60901833; called by muse, varscan2
- OTOF | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs751650771, COSV55498169; called by muse, mutect2, varscan2
- SLC27A1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.227); catalogued as rs754160792, COSV53097133; called by muse, mutect2, varscan2
- SPG11 | c.5650C>T p.R1884C | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs752889027, COSV55999142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D16 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs145310382; called by muse, varscan2
- TENM2 | c.3076C>T p.R1026W (on ENST00000518659 / NM_001122679.2; = p.R794W on NM_001080428.3) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755881164, COSV69143655; called by muse, mutect2, varscan2
- CASP8 | c.523A>T p.I175F (on ENST00000432109 / NM_033355.3; = p.I207F on NM_001228.4) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CCDC125 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- CSMD1 | c.6081C>A p.D2027E (on ENST00000520002; = p.D2026E on NM_033225.6) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSNK2A1 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXW7 | c.1630G>T p.V544F (on ENST00000281708 / NM_001349798.2; = p.V464F on NM_018315.5) | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC6 | c.867T>A p.N289K | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- NCKAP5 | c.3539A>G p.K1180R | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PARP14 | c.467T>G p.L156R | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PPP1R12A | c.1455+1G>C p.X485_splice | Splice Site (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- TCF20 | c.2451G>T p.W817C | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM131 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRPA1 | c.3041G>C p.G1014A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- AMER2 | c.1503T>C p.H501= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- FRAS1 | c.7317G>A p.T2439= | Silent (SNP) | VAF 48/180 reads (27%) | catalogued as rs369764135, COSV53591885; called by muse, mutect2, varscan2
- IQGAP2 | c.450C>T p.H150= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs780934953, COSV57167882, COSV99059498; called by muse, mutect2, varscan2
- PPFIA1 | c.1869C>T p.A623= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs149630964; called by muse, mutect2, varscan2
- PRDM1 | c.1197G>A p.P399= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs372762124; called by muse, mutect2, varscan2
- TTN | c.26835G>T p.L8945= (on ENST00000591111; = p.L8018= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- UNC13C | c.4068T>C p.V1356= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- VPS13D | c.5052A>G p.K1684= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- ZBTB21 | c.621T>C p.S207= | Silent (SNP) | VAF 69/281 reads (25%) | catalogued as COSV60403317; called by muse, mutect2, varscan2
- PIK3R1 | c.635-10A>T | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as rs769498194; called by muse, mutect2, varscan2
- USP9X | c.3978-311T>C | Intron (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
